Somatic mutation profile of tumor specimen C3L-01288-02 (aliquot CPT0079230009) from CPTAC case C3L-01288, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 70.9 years (25,898 days).
Specimen C3L-01288-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc33b087-e85c-4435-a2b0-7a244153f169.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01288-31 (Blood Derived Normal), aliquot CPT0080100002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81f659f3-d0e2-4431-b93e-28fdc3c1fbb7

The open-access MAF lists 113 somatic variants for this specimen: 81 protein-altering or splice-affecting, 15 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 15, Intron 11, Frame Shift Ins 5, Frame Shift Del 5, Splice Site 4, 3'UTR 2, In Frame Del 2, 5'Flank 2, Splice Region 2, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.221T>A p.V74D | Missense Mutation (SNP) | VAF 200/420 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs5030803, CM961417, COSV56542909, COSV56544662, COSV56545202, COSV56545701; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP3B2 | c.110A>C p.K37T | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.074); catalogued as rs1025914031; called by muse, mutect2, varscan2
- AP4E1 | c.255A>G p.I85M | Missense Mutation (SNP) | VAF 97/424 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.115); catalogued as rs771939364; called by muse, varscan2
- ATF4 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs367700144; called by muse, mutect2, varscan2
- ATP2B2 | c.709G>T p.D237Y | Missense Mutation (SNP) | VAF 21/344 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100660605; called by muse, mutect2
- BRCA2 | c.2268G>T p.Q756H | Missense Mutation (SNP) | VAF 39/544 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV66449160; called by muse, mutect2
- CACNA2D1 | c.2626G>A p.G876R (on ENST00000356253 / NM_001366867.1; = p.G864R on NM_000722.4) | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100667025; called by muse, mutect2
- CDK4 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 142/585 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57275477; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3784G>C p.D1262H | Missense Mutation (SNP) | VAF 20/449 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1164071941; called by muse, mutect2
- GNS | c.904C>A p.L302I | Missense Mutation (SNP) | VAF 132/515 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV50693902; called by muse, mutect2, varscan2
- ITPKB | c.2460C>A p.D820E | Missense Mutation (SNP) | VAF 54/370 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as rs112559528; called by muse, mutect2, varscan2
- LAMA2 | c.1507G>A p.G503S | Missense Mutation (SNP) | VAF 123/560 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs375232037; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRAP | c.1649G>A p.G550D (on ENST00000359988 / NM_001322945.2; = p.G515D on NM_006175.4) | Missense Mutation (SNP) | VAF 48/224 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.174); catalogued as COSV104418184; called by muse, mutect2, varscan2
- PARP11 | c.542T>G p.F181C | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1323721200; called by muse, mutect2, varscan2
- PHLDB1 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 52/209 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as rs145152438; called by muse, varscan2
- RASA1 | c.3037A>T p.S1013C | Missense Mutation (SNP) | VAF 116/558 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56924471; called by muse, mutect2, varscan2
- REG1B | c.427T>G p.C143G | Missense Mutation (SNP) | VAF 54/271 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV59305339; called by muse, mutect2, varscan2
- TMPRSS15 | c.112G>T p.V38L | Missense Mutation (SNP) | VAF 24/438 reads (5%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV99517743; called by muse, mutect2
- TRRAP | c.4510C>T p.P1504S | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.901); catalogued as rs1554416645; called by muse, mutect2, varscan2
- TRRAP | c.6091G>C p.D2031H (on ENST00000359863 / NM_001244580.1; = p.D2013H on NM_003496.3) | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as COSV62848433; called by muse, mutect2, varscan2
- ABHD11 | c.215del p.L72Cfs*27 | Frame Shift Del (DEL) | VAF 40/180 reads (22%) | called by mutect2, pindel, varscan2
- ABITRAM | c.364_368del p.V122* | Frame Shift Del (DEL) | VAF 22/174 reads (13%) | called by mutect2, pindel, varscan2
- ANKS3 | c.1117_1119+8del p.X373_splice | Splice Site (DEL) | VAF 21/107 reads (20%) | called by mutect2, pindel
- ANKZF1 | c.2099C>G p.P700R | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AP3M1 | c.38A>C p.D13A | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.151); called by muse, mutect2
- ARHGAP32 | c.2474C>G p.S825C (on ENST00000310343 / NM_001378025.1; = p.S476C on NM_014715.4) | Missense Mutation (SNP) | VAF 15/315 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.321); called by muse, mutect2
- ASTL | c.433dup p.I145Nfs*39 | Frame Shift Ins (INS) | VAF 55/241 reads (23%) | called by mutect2, pindel, varscan2
- ATF7IP | c.1608dup p.V537Sfs*4 | Frame Shift Ins (INS) | VAF 26/186 reads (14%) | called by mutect2, pindel, varscan2
- ATG9B | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ATP8A1 | c.16A>G p.R6G | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BEND5 | c.41_50delinsG p.Y14_P17delinsC | In Frame Del (DEL) | VAF 20/180 reads (11%) | called by pindel, varscan2*
- C1R | c.40C>G p.Q14E | Missense Mutation (SNP) | VAF 53/270 reads (20%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- CA4 | c.514-6T>C | Splice Region (SNP) | VAF 67/347 reads (19%) | called by muse, mutect2, varscan2
- CCDC168 | c.6920C>A p.S2307* | Nonsense Mutation (SNP) | VAF 48/279 reads (17%) | called by muse, mutect2, varscan2
- CDK11B | c.789dup p.Q264Tfs*41 | Frame Shift Ins (INS) | VAF 5/29 reads (17%) | called by mutect2, varscan2
- CHSY3 | c.950T>C p.F317S | Missense Mutation (SNP) | VAF 78/657 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- CLCN7 | c.146C>A p.P49Q | Missense Mutation (SNP) | VAF 132/739 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CPA2 | c.972T>G p.D324E | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPPED1 | c.325A>C p.K109Q | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CUL7 | c.3699C>G p.I1233M | Missense Mutation (SNP) | VAF 106/380 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DHX37 | c.3097C>A p.L1033M | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DMGDH | c.773T>G p.M258R | Missense Mutation (SNP) | VAF 155/375 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DPH7 | c.973del p.L325* | Frame Shift Del (DEL) | VAF 17/73 reads (23%) | called by mutect2, pindel, varscan2
- DPY30 | c.160C>G p.R54G | Missense Mutation (SNP) | VAF 37/382 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- DYNC2I2 | c.553C>A p.H185N | Missense Mutation (SNP) | VAF 76/275 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- FAM83G | c.2395A>G p.R799G | Missense Mutation (SNP) | VAF 46/244 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- FBXL16 | c.554_559del p.I185_D186del | In Frame Del (DEL) | VAF 42/116 reads (36%) | called by mutect2, pindel, varscan2
- FNBP1 | c.346-1G>T p.X116_splice | Splice Site (SNP) | VAF 61/219 reads (28%) | called by muse, mutect2, varscan2
- GGT7 | c.1233C>G p.T411= | Splice Region (SNP) | VAF 41/194 reads (21%) | called by muse, mutect2, varscan2
- GPR1 | c.184T>A p.F62I | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT tolerated (0.81); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- GPR137B | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 86/383 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HDHD3 | c.119T>C p.V40A | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.866); called by mutect2, varscan2
- HDX | c.1465A>C p.N489H | Missense Mutation (SNP) | VAF 63/270 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KHDC4 | c.823G>T p.G275C | Missense Mutation (SNP) | VAF 137/545 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMA2 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 124/562 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MACF1 | c.19751_19754del p.I6584Nfs*31 (on ENST00000372915; = p.I4629Nfs*31 on NM_012090.5) | Frame Shift Del (DEL) | VAF 28/136 reads (21%) | called by mutect2, varscan2
- MAGEB1 | c.830A>C p.Y277S | Missense Mutation (SNP) | VAF 34/470 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- MIA2 | c.249T>G p.S83R | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MOCOS | c.1372G>T p.D458Y | Missense Mutation (SNP) | VAF 98/356 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MPDU1 | c.601dup p.I201Nfs*101 | Frame Shift Ins (INS) | VAF 109/444 reads (25%) | called by mutect2, pindel, varscan2
- MYH13 | c.1894+1G>T p.X632_splice | Splice Site (SNP) | VAF 15/50 reads (30%) | called by muse, varscan2
- MYH6 | c.2977A>G p.K993E | Missense Mutation (SNP) | VAF 96/278 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- NFXL1 | c.1525_1543+1del p.X509_splice | Splice Site (DEL) | VAF 42/208 reads (20%) | called by mutect2, pindel, varscan2
- NR2F2 | c.734T>G p.L245R | Missense Mutation (SNP) | VAF 82/301 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OSBPL6 | c.2347A>G p.I783V | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDHA1 | c.2096A>G p.Y699C | Missense Mutation (SNP) | VAF 173/556 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PML | c.2270T>A p.L757H | Missense Mutation (SNP) | VAF 84/252 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.124T>C p.C42R (on ENST00000421990 / NM_001136042.2; = p.C24R on NM_025267.3) | Missense Mutation (SNP) | VAF 81/386 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PYM1 | c.407C>T p.T136I | Missense Mutation (SNP) | VAF 80/353 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RBM12B | c.2405A>C p.D802A | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RIOK3 | c.1331G>T p.R444M | Missense Mutation (SNP) | VAF 41/484 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.905); called by muse, mutect2
- RNF43 | c.1064C>A p.A355D | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- SDE2 | c.695A>G p.D232G | Missense Mutation (SNP) | VAF 86/306 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- SLC22A12 | c.1147A>G p.M383V | Missense Mutation (SNP) | VAF 107/496 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNX9 | c.1176dup p.V393Sfs*19 | Frame Shift Ins (INS) | VAF 71/270 reads (26%) | called by mutect2, pindel, varscan2
- ST6GAL2 | c.611T>C p.L204P | Missense Mutation (SNP) | VAF 79/282 reads (28%) | PolyPhen benign (0.038); called by muse, mutect2, varscan2
- STRADB | c.632A>C p.K211T | Missense Mutation (SNP) | VAF 46/258 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- TENT5A | c.425T>C p.L142P | Missense Mutation (SNP) | VAF 61/256 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM10 | c.866del p.P289Rfs*6 | Frame Shift Del (DEL) | VAF 67/231 reads (29%) | called by mutect2, pindel, varscan2
- XPC | c.1664C>T p.P555L | Missense Mutation (SNP) | VAF 206/413 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ZSCAN4 | c.802A>C p.M268L | Missense Mutation (SNP) | VAF 88/380 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- AADACL3 | c.792A>G p.Q264= | Silent (SNP) | VAF 41/231 reads (18%) | called by muse, mutect2, varscan2
- ALDH2 | c.678G>A p.K226= | Silent (SNP) | VAF 54/233 reads (23%) | called by muse, mutect2, varscan2
- APH1A | c.102C>T p.I34= | Silent (SNP) | VAF 57/209 reads (27%) | called by muse, mutect2, varscan2
- CERS5 | c.75G>A p.E25= | Silent (SNP) | VAF 19/150 reads (13%) | called by muse, mutect2, varscan2
- CFAP251 | c.2727G>T p.A909= | Silent (SNP) | VAF 41/130 reads (32%) | called by muse, mutect2, varscan2
- CHD4 | c.3951C>G p.A1317= (on ENST00000357008 / NM_001363606.2; = p.A1330= on NM_001273.5) | Silent (SNP) | VAF 41/219 reads (19%) | catalogued as COSV100537939; called by muse, mutect2, varscan2
- CNOT4 | c.972C>T p.S324= (on ENST00000315544 / NM_001190848.1; = p.S321= on NM_013316.4) | Silent (SNP) | VAF 82/388 reads (21%) | called by muse, mutect2, varscan2
- IQSEC2 | c.3192C>T p.P1064= (on ENST00000642864 / NM_001111125.3; = p.P859= on NM_015075.2) | Silent (SNP) | VAF 136/543 reads (25%) | called by muse, mutect2, varscan2
- MAST4 | c.7227G>A p.G2409= (on ENST00000403625 / NM_001164664.2; = p.G2220= on NM_015183.3) | Silent (SNP) | VAF 34/105 reads (32%) | catalogued as rs777251926; called by muse, mutect2, varscan2
- MYO1E | c.2955G>A p.Q985= | Silent (SNP) | VAF 101/454 reads (22%) | called by muse, mutect2, varscan2
- NRAP | c.1650C>A p.G550= (on ENST00000359988 / NM_001322945.2; = p.G515= on NM_006175.4) | Silent (SNP) | VAF 52/230 reads (23%) | called by muse, mutect2, varscan2
- PIK3R3 | c.1110C>T p.D370= | Silent (SNP) | VAF 61/298 reads (20%) | called by muse, mutect2, varscan2
- RABEP1 | c.1989G>A p.Q663= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as rs1293075876; called by muse, mutect2, varscan2
- SIK2 | c.1623C>G p.A541= | Silent (SNP) | VAF 49/194 reads (25%) | called by muse, mutect2, varscan2
- SLC4A4 | c.1815C>A p.I605= (on ENST00000264485 / NM_001098484.3; = p.I561= on NM_003759.4) | Silent (SNP) | VAF 22/400 reads (6%) | catalogued as COSV52619127; called by muse, mutect2
- ACSF3 | c.-101C>G | 5'UTR (SNP) | VAF 40/456 reads (9%) | called by muse, mutect2
- AL353804.7 | chrX:73849400 A>G | 5'Flank (SNP) | VAF 179/782 reads (23%) | called by muse, mutect2, varscan2
- ATAD3B | c.*303G>A | 3'UTR (SNP) | VAF 102/467 reads (22%) | called by muse, mutect2, varscan2
- BEST1 | c.1740-51A>G | Intron (SNP) | VAF 56/235 reads (24%) | called by muse, mutect2, varscan2
- CCDC18 | c.-3+361T>G | Intron (SNP) | VAF 50/217 reads (23%) | called by muse, mutect2, varscan2
- ELP1 | c.740+30_740+33del | Intron (DEL) | VAF 99/367 reads (27%) | called by mutect2, pindel, varscan2
- FRMD3 | c.1196-18584C>T | Intron (SNP) | VAF 81/357 reads (23%) | called by muse, mutect2, varscan2
- GPM6A | c.-23+31423G>A | Intron (SNP) | VAF 48/248 reads (19%) | called by muse, mutect2, varscan2
- HDAC4 | c.2373+54C>A | Intron (SNP) | VAF 58/236 reads (25%) | called by muse, mutect2, varscan2
- MAP2K2 | c.706-31C>T | Intron (SNP) | VAF 36/127 reads (28%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.2425-67102C>A | Intron (SNP) | VAF 59/242 reads (24%) | called by muse, mutect2, varscan2
- POLR2G | c.12+9G>C | Intron (SNP) | VAF 20/73 reads (27%) | catalogued as rs763149393; called by muse, mutect2, varscan2
- SGSH | c.746-23T>C | Intron (SNP) | VAF 117/438 reads (27%) | called by muse, mutect2, varscan2
- SMIM9 | c.*21G>T | 3'UTR (SNP) | VAF 24/122 reads (20%) | called by muse, mutect2, varscan2
- TMEM67 | chr8:93819081 G>A | 3'Flank (SNP) | VAF 20/221 reads (9%) | catalogued as rs758830937; called by muse, mutect2
- WARS1 | c.99+629C>A | Intron (SNP) | VAF 50/172 reads (29%) | called by muse, mutect2, varscan2
- ZNF252P | chr8:145003211 C>G | 5'Flank (SNP) | VAF 93/298 reads (31%) | called by muse, mutect2, varscan2
